Somatic mutation profile of tumor specimen TCGA-B8-4151-01A (aliquot TCGA-B8-4151-01A-01D-1806-10) from TCGA case TCGA-B8-4151, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 51.4 years (18,760 days).
Specimen TCGA-B8-4151-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2c6d1e7-276e-4822-b133-2536ebd534e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4151-10A (Blood Derived Normal), aliquot TCGA-B8-4151-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12e054bd-0973-4818-a884-420a944cd236

The open-access MAF lists 51 somatic variants for this specimen: 43 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 35, Silent 8, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2A | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV54025497; called by muse, mutect2, varscan2
- APOH | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52773575; called by muse, mutect2, varscan2
- ATP5MC2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58601745; called by muse, mutect2, varscan2
- ATRX | c.4709T>G p.F1570C | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64879661; called by muse, mutect2, varscan2
- BAP1 | c.2149del p.R717Gfs*19 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as COSV56232501; called by mutect2, varscan2
- C11orf94 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs540548996, COSV53798843; called by muse, mutect2, varscan2
- C6orf62 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV57764440; called by muse, mutect2, varscan2
- CNOT11 | c.1514A>C p.E505A | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.257); catalogued as COSV56820490; called by muse, mutect2, varscan2
- COL26A1 | c.247T>A p.C83S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58128020; called by muse, varscan2
- CTCF | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50482017; called by muse, mutect2, varscan2
- CYP46A1 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.645); catalogued as COSV55895568; called by muse, mutect2
- DENND2D | c.59T>A p.L20H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV62959527; called by muse, mutect2, varscan2
- FGF9 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 6/121 reads (5%) | catalogued as COSV66644771, COSV66645128; called by muse, mutect2
- GDF3 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV61713049; called by muse, varscan2
- GDF3 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as COSV61713061; called by muse, varscan2
- KLRC1 | c.168C>A p.D56E | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.569); catalogued as COSV61725520; called by muse, mutect2, varscan2
- KMT2D | c.11324G>A p.G3775D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs935804499, COSV56460780; called by muse, mutect2, varscan2
- LIME1 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.011); catalogued as COSV55511990; called by muse, mutect2, varscan2
- MAP1A | c.7844C>A p.P2615Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55810620; called by muse, mutect2, varscan2
- NCL | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV59546742; called by muse, mutect2, varscan2
- PAK4 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1170645214, COSV58945756; called by muse, mutect2, varscan2
- PCTP | c.620G>C p.C207S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52123105; called by muse, mutect2, varscan2
- PGR | c.2015G>C p.R672T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV54805392, COSV99678530; called by muse, mutect2, varscan2
- PLEKHG3 | c.1236+2T>C p.X412_splice (on ENST00000394691; = p.X468_splice on NM_001308147.2) | Splice Site (SNP) | VAF 31/70 reads (44%) | catalogued as COSV55981488; called by muse, mutect2, varscan2
- RAD51AP1 | c.1006T>A p.L336M (on ENST00000228843 / NM_001130862.2; = p.L319M on NM_006479.5) | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57411017; called by muse, mutect2, varscan2
- RAPGEF2 | c.3395C>T p.A1132V | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs546918296, COSV52430626; called by muse, mutect2, varscan2
- REXO4 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64241937; called by muse, mutect2, varscan2
- SALL1 | c.3015T>G p.I1005M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV51760724; called by muse, mutect2, varscan2
- SALL1 | c.3014T>A p.I1005N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51760734; called by muse, mutect2, varscan2
- SLC44A3 | c.1667A>C p.N556T (on ENST00000271227 / NM_001114106.3; = p.N508T on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 218/602 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54731802; called by muse, mutect2, varscan2
- SLC6A8 | c.425T>A p.F142Y | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.566); catalogued as COSV53472767; called by muse, mutect2, varscan2
- SP140 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59452089; called by muse, mutect2, varscan2
- TRIM62 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); catalogued as rs1231263068, COSV52222311; called by muse, mutect2, varscan2
- TUBGCP6 | c.4790A>G p.D1597G | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50558754; called by muse, mutect2, varscan2
- USH2A | c.6709G>T p.D2237Y | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs1177455978, CM104141, COSV56397260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNRD2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs912902524, COSV57079776; called by muse, mutect2, varscan2
- CWC25 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHX1 | c.259A>C p.N87H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PBRM1 | c.147del p.C50Afs*45 | Frame Shift Del (DEL) | VAF 29/54 reads (54%) | called by mutect2, pindel, varscan2
- RAPGEF2 | c.3018_3019+1dup | Nonsense Mutation (INS) | VAF 10/36 reads (28%) | called by pindel, varscan2
- SFSWAP | c.848_855del p.S283* | Frame Shift Del (DEL) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D9B | c.2326del p.S776Afs*2 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | called by mutect2, pindel, varscan2
- ZNF12 | c.619del p.Y207Ifs*42 (on ENST00000405858 / NM_016265.4; = p.Y169Ifs*42 on NM_006956.3) | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- FLAD1 | c.1125T>G p.S375= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV52698197; called by muse, mutect2, varscan2
- IRAG1 | c.1779G>C p.R593= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1173118509, COSV70212011; called by muse, mutect2, varscan2
- KDM3B | c.4272C>T p.L1424= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV58692723; called by muse, mutect2
- NPAS4 | c.189G>A p.A63= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV100214814, COSV60651436; called by muse, mutect2, varscan2
- SCOC | c.479A>G p.*160= (on ENST00000608372; = p.*123= on NM_032547.3) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV58393356; called by muse, mutect2, varscan2
- SHCBP1L | c.1929C>T p.N643= | Silent (SNP) | VAF 58/172 reads (34%) | catalogued as rs775141845, COSV62355921; called by muse, mutect2, varscan2
- TAC3 | c.93T>A p.V31= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV55648479; called by muse, mutect2
- VSIG8 | c.627G>A p.E209= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV63653263; called by muse, mutect2, varscan2
